Somatic mutation profile of tumor specimen 0DPBGW from CCDI case PBCDKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 0.0 years (10 days).
Specimen 0DPBGW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bdef140-1aa8-405a-b08a-3a10de9ba147.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPBFE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/990415ee-b534-44d1-98c8-b2c4355feca7

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 857/1155 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DNAH11 | c.10493C>T p.P3498L | Missense Mutation (SNP) | VAF 153/1747 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485658856; called by muse, mutect2
- TTC7A | c.665C>A p.T222K | Missense Mutation (SNP) | VAF 770/1783 reads (43%) | SIFT tolerated (0.98); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AMPD2 | c.2377C>T p.L793= | Silent (SNP) | VAF 255/774 reads (33%) | called by muse, mutect2, varscan2
- CTDSP1 | c.-91C>T | 5'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
